Somatic mutation profile of tumor specimen C3L-01458-01 (aliquot CPT0390170006) from CPTAC case C3L-01458, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 60.1 years (21,969 days).
Specimen C3L-01458-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82401a69-e71d-49ec-bd4d-8be96a0ba78b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01458-31 (Blood Derived Normal), aliquot CPT0390230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92d39061-d5fb-4cb7-bfb6-bcc88809f88b

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 3, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYTL1 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 122/412 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.039); catalogued as COSV57036649; called by muse, mutect2, varscan2
- IGHV4-28 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 143/316 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.491); catalogued as rs782085195; called by muse, mutect2, varscan2
- KANK1 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs1461968456; called by muse, mutect2, varscan2
- KCNA5 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 21/395 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99363896; called by muse, mutect2
- NCKIPSD | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs752761276; called by muse, mutect2, varscan2
- OXR1 | c.122C>A p.P41Q (on ENST00000442977 / NM_001198532.1; = p.P40Q on NM_018002.3) | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.443); catalogued as rs767188608; called by muse, mutect2, varscan2
- POLN | c.2248G>T p.A750S | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as COSV101242519; called by muse, mutect2, varscan2
- SLC29A3 | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs375978498; called by muse, mutect2, varscan2
- SPG21 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 112/348 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs764559344, COSV99200193; called by muse, mutect2, varscan2
- EXPH5 | c.1651del p.W551Gfs*23 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- HPS5 | c.2710G>A p.D904N (on ENST00000349215 / NM_181507.2; = p.D790N on NM_007216.4) | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.407); called by mutect2, varscan2
- P2RY6 | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 128/424 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAM | c.223T>A p.F75I | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLXNA4 | c.3193C>A p.L1065M | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBAK | c.1642T>A p.F548I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA3D | c.497A>C p.D166A | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SMARCA2 | c.3412G>C p.A1138P | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSFM | c.896A>C p.E299A (on ENST00000323833 / NM_001172696.2; = p.E278A on NM_005726.6) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, varscan2
- WDR97 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 126/400 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EYS | c.5766T>C p.Y1922= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs111663949; ClinVar: likely benign; called by muse, mutect2, varscan2
- MICAL3 | c.5232C>T p.F1744= | Silent (SNP) | VAF 40/394 reads (10%) | called by muse, mutect2, varscan2
- SEMA4C | c.2251C>A p.R751= | Silent (SNP) | VAF 81/253 reads (32%) | catalogued as COSV59690964; called by muse, mutect2, varscan2
- SVIL | c.4092C>T p.P1364= (on ENST00000355867 / NM_021738.3; = p.P938= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/260 reads (12%) | called by muse, varscan2
- TUBGCP4 | c.1998G>A p.G666= (on ENST00000260383 / NM_001286414.3; = p.G665= on NM_014444.5) | Silent (SNP) | VAF 52/170 reads (31%) | called by muse, mutect2, varscan2
- C5orf58 | c.-64A>T | 5'UTR (SNP) | VAF 72/263 reads (27%) | called by muse, mutect2, varscan2
- HLA-DQB1 | c.-4A>C | 5'UTR (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- MMP2 | c.154-1062A>G | Intron (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.10361-5166C>T | Intron (SNP) | VAF 20/59 reads (34%) | catalogued as rs376396183, COSV60007588; called by muse, mutect2, varscan2
- UMODL1 | c.931+3472C>T | Intron (SNP) | VAF 45/257 reads (18%) | called by muse, mutect2, varscan2
